Somatic mutation profile of tumor specimen MBCProject_5856_T2_WES (aliquot MBCProject_5856_T2_WES_1) from CMI case MBCProject_5856, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 60.0 years (21,902 days).
Specimen MBCProject_5856_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb78b1a2-7540-4ffb-8939-34b2ae062f8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_5856_SALIVA (Saliva), aliquot MBCProject_5856_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/400d8879-e564-4f01-8a89-10a837f2b36d

The open-access MAF lists 27 somatic variants for this specimen: 14 protein-altering or splice-affecting, 7 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 7, Intron 4, 5'Flank 1, Frame Shift Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM7 | c.1837G>C p.G613R | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); catalogued as rs778041314, COSV51539239; called by muse, mutect2, varscan2
- CCDC197 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs748749118, COSV58939316; called by muse, mutect2, varscan2
- GDPD4 | c.1021C>G p.L341V | Missense Mutation (SNP) | VAF 351/826 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.534); catalogued as rs1210817231, COSV60017262; called by muse, mutect2, varscan2
- GOT1L1 | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.027); catalogued as rs1408567571; called by muse, mutect2, varscan2
- KCNH8 | c.1621C>T p.H541Y | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as rs755839538; called by muse, mutect2, varscan2
- OLIG2 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV100324383, COSV60973530; called by muse, mutect2, varscan2
- PRLH | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs770338709; called by muse, mutect2, varscan2
- SLCO1C1 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs754805185; called by muse, varscan2
- FLNA | c.4799A>C p.H1600P | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.233); called by muse, mutect2
- GDPD4 | c.1105C>T p.H369Y | Missense Mutation (SNP) | VAF 187/423 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDHGB2 | c.1219del p.D407Tfs*30 | Frame Shift Del (DEL) | VAF 24/113 reads (21%) | called by mutect2, pindel, varscan2
- PXDNL | c.1526-6_1538del p.X509_splice | Splice Site (DEL) | VAF 12/101 reads (12%) | called by mutect2, pindel
- SOX6 | c.721C>A p.Q241K | Missense Mutation (SNP) | VAF 61/379 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- SPHKAP | c.3396C>A p.F1132L | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ARHGAP10 | c.1455C>T p.S485= | Silent (SNP) | VAF 19/133 reads (14%) | catalogued as rs372408519; called by muse, mutect2, varscan2
- CAPNS1 | c.141C>T p.G47= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as rs17879825; called by muse, varscan2
- CTNS | c.39C>G p.P13= | Silent (SNP) | VAF 48/176 reads (27%) | called by muse, mutect2, varscan2
- KIAA1755 | c.1104G>A p.P368= | Silent (SNP) | VAF 39/200 reads (20%) | catalogued as rs371997422, COSV54073610; called by muse, mutect2, varscan2
- PTER | c.645A>T p.I215= | Silent (SNP) | VAF 29/150 reads (19%) | called by muse, mutect2, varscan2
- RHCE | c.132C>T p.L44= | Silent (SNP) | VAF 51/236 reads (22%) | catalogued as rs768223782, COSV99604050; called by muse, mutect2, varscan2
- ZNF726 | c.1719G>A p.A573= | Silent (SNP) | VAF 34/154 reads (22%) | catalogued as rs770183581, COSV58043956; called by muse, mutect2, varscan2
- AOX3P | chr2:200676927 T>C | 5'Flank (SNP) | VAF 45/230 reads (20%) | called by muse, mutect2, varscan2
- DOCK11 | c.3292+499dup | Intron (INS) | VAF 24/128 reads (19%) | called by mutect2, varscan2
- ENPEP | c.1510-912G>T | Intron (SNP) | VAF 45/219 reads (21%) | catalogued as rs1001340490; called by muse, mutect2, varscan2
- PIGK | c.987-6966G>A | Intron (SNP) | VAF 45/385 reads (12%) | catalogued as rs1156950126; called by muse, mutect2, varscan2
- PTENP1 | n.1081C>T | RNA (SNP) | VAF 39/260 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.34264+5686G>T | Intron (SNP) | VAF 14/95 reads (15%) | called by muse, mutect2
